Gene-level copy-number profile of specimen HCM-BROD-0101-C15-85A from HCMI case HCM-BROD-0101-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 64.0 years (23,385 days).
Specimen HCM-BROD-0101-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae493181-b149-4ef1-bcb9-d64f530290ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0101-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/e3afea5b-4283-43b5-8e34-caa171dd21f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 463; copy number 1: 3,635; copy number 2: 32,764; copy number 3: 15,905; copy number 4: 5,705; copy number 5: 118; copy number 6: 94; copy number 7: 156; copy number 9: 22; copy number 10: 28; copy number 11: 12; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:153,421,616–153,593,288, 3 genes (within-gene range 0–1): AC012501.2, AC012501.1, RPRM.
- chr15:85,180,200–85,234,795, 1 gene (within-gene range 0–2): AC044860.1.
- chr15:85,210,053–85,210,299, 1 gene (within-gene range 0–2): RN7SL428P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 431 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,911,553–120,100,779, 2 genes, copy number 5: NOTCH2, AC245008.1.
- chr1:121,184,811–121,580,524, 9 genes, copy number 5 (within-gene range 4–7): SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr6:54,770,583–55,579,197, 8 genes, copy number 6–7: KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1.
- chr6:55,753,653–57,222,307, 19 genes, copy number 6–7: BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23.
- chr7:92,971,002–96,940,364, 62 genes, copy number 5 (broad region; genes not listed).
- chr7:97,117,698–101,180,293, 164 genes, copy number 5–7 (broad region; genes not listed).
- chr8:40,530,590–42,796,392, 48 genes, copy number 5–9: ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6.
- chr11:32,112,049–32,458,769, 10 genes, copy number 5: THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr11:33,376,108–33,674,102, 1 gene, copy number 6 (within-gene range 4–6): KIAA1549L.
- chr11:33,665,220–33,822,378, 11 genes, copy number 6: AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721.
- chr11:34,049,967–34,102,610, 2 genes, copy number 6: AC090469.1, CAPRIN1.
- chr13:75,871,038–77,327,094, 18 genes, copy number 5–6: LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1, MYCBP2, MYCBP2-AS2.
- chr18:20,946,906–24,397,880, 77 genes, copy number 5–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,760. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
